Surgical pathology report (de-identified scan), TCGA case TCGA-CV-7433, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-7433-01A (Primary Tumor).

[page 1 of 3]
SUPPLEMENTAL REPORT

DIAGNOSIS:

(F) TEETH:

Gross examination only.

COMMENT:

This report is being issued to add the (F) diagnosis. The rest of the diagnoses are unchanged.

DIAGNOSIS

(A) LOWER JUGULAR NODES, LEFT SIDE:

Fourteen lymph nodes, no tumor present.

(B) ESOPHAGEAL MARGIN:

Focal mild dysplasia and detached fragments with dysplasia/atypia (cannot grade since not full thickness).

(C) SUPERIOR LARYNGEAL NERVE, RIGHT SIDE:

Peripheral nerve and soft tissue, no tumor present.

(D) SUPERIOR PHARYNGEAL MARGIN:

Mucosa, submucosa, muscle, no severe dysplasia or invasive carcinoma.

(E) LARYNGOPHARYNGECTOMY, RIGHT NECK DISSECTION, RIGHT THYROID LOBE:

INVASIVE-SQUAMOUS CARCINOMA, POORLY DIFFERENTIATED, 6.5 X 2.5 CM, INVOLVING MID SUPRAGLOTTIC AND EXTENDING TO THE RIGHT AND LEFT GLOTTIS; MARGINS FREE OF INVASIVE CARCINOMA. METASTATIC CARCINOMA IN 4 OF 29 LYMPH NODES (UPPER MID AND LOWER JUGULAR LYMPH NODES) WITH EXTRANODAL EXTENSION.

[page 2 of 3]
GROSS DESCRIPTION

(A) LOWER JUGULAR NODES, LEFT SIDE - A segment of fatty yellow soft tissue containing multiple lymph nodes ranging from 0.5 cm to 1.0 cm. All lymph nodes are submitted in toto.

SECTION CODE: A1, four lymph nodes; A2, one lymph node; A3, three lymph nodes, A4, one lymph node; A5, three lymph nodes; A6, one lymph node.

(B) ESOPHAGEAL MARGIN - The specimen consists of a strip of mucosa (6.5 x 0.8 x 0.3 cm in greatest dimensions). The specimen is divided into two segments and submitted entirely for frozen section in B1 and B2.

*FS/DX: FOCAL MILD DYSPLASIA AND DETACHED FRAGMENTS WITH DYSPLASIA/ATYPIA (CANNOT GRADE SINCE NOT FULL-THICKNESS).

(C) SUPERIOR LARYNGEAL NERVE, RIGHT SIDE - A 0.4 x 0.2 x 0.2 cm tan fragment, entirely submitted in C for frozen section.

*FS/DX: NERVE SEGMENT AND ADJACENT SOFT TISSUE, NO TUMOR PRESENT.

(D) SUPERIOR PHARYNGEAL MARGIN - The specimen consists of a 1.2 x 0.5 x 0.2 cm portion of tan mucosa. A second smaller portion of tan mucosa which is 0.5 x 0.4 x 0.2 cm is also present. No nodules or masses are identified. No orientation is provided. Entirely submitted for frozen section in D.

*FS/DX: MUCOSA, SUBMUCOSA, MUSCLE. NO SEVERE DYSPLASIA OR INVASIVE CARCINOMA. (CANNOT RULE OUT FOCAL MILD DYSPLASIA-TOO CAUTERIZED TO EVALUATE).

(E) LARYNGEAL PHARYNGECTOMY AND RIGHT NECK DISSECTION, INCLUDING JUGULAR VEIN AND RIGHT THYROID LOBE - A product of laryngeal pharyngectomy and right neck dissection with overall measurements of 10.0 x 9.0 x 5.5 cm. On the right supraglottic area and involving the right glottic and midline is a large mass with overall measurements of 6.0 x 6.5 x 2.5 cm. The mass is fungating, ulcerative, and deeply invading to cartilage and involving the right and middle supraglottic area, including the right glottic and midline. The mucosal and deep margin of resections are grossly uninvolved. Lymph nodes are identified on both the right and left aspects of the laryngeal pharyngectomy specimen. The left lymph nodes correspond to the "middle and inferior" lymph nodes. The left lymph node dissection consists of a 2.5 x 1.5 x 0.5 cm portion of fibrofatty tissue containing two lymph nodes ranging from 1.5 to 1.4 cm in maximum dimension. The right lymph node dissection is 8.5 x 2.5 x 2.0 cm portion of fibrofatty adipose tissue containing upper, mid, and lower jugular lymph nodes. Multiple lymph nodes are identified in all levels ranging from 0.5 to 1.8 cm in maximum dimension.

SECTION CODE: Representative sections of tumor and adjacent mucosa from right to left side from E1-E13, mucosal margin circumferentially from right to left from E14-E19 and E21; E20, representative section of the left glottic area; E22, representative section of thyroid; E23 and E24, tracheal margin of resection. The left and right neck dissections are submitted as follows: E25, left lymph nodes, corresponding to "middle-inferior"; E26, one lymph node, corresponding to left "middle/inferior" lymph node; E27-E48, right neck lymph nodes submitted as follows: (E27-E30 right upper jugular lymph nodes, E31 one right upper jugular lymph node, E32 one right upper jugular lymph node, E33 one right upper jugular lymph node, E34 one right mid jugular lymph node, E35 one right mid jugular lymph node, E36-E38 one right mid jugular lymph node, E39-E45 one right lower jugular lymph node, E46 one right lower jugular lymph

[page 3 of 3]
[REDACTED]

node, E47 one right lower jugular lymph node, E48 one right lower jugular lymph node).

COMMENT: The lymph nodes are submitted from superior to inferior. [REDACTED]
(F) TEETH - Five unremarkable teeth (3.5 x 3.0 x 2.0 cm in aggregate). Gross examination only. [REDACTED]

SNOMED CODES

M-80703 T-24100

Source: NCI Genomic Data Commons file bbfde064-37e8-4984-934c-3fa1c54b6c05 (TCGA-CV-7433.C84F6573-7C53-41C4-81C3-D666F30F483D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).